Somatic mutation profile of tumor specimen MP2PRT-PATGAM-TMP1-A (aliquot MP2PRT-PATGAM-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATGAM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.9 years (2,507 days).
Specimen MP2PRT-PATGAM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47a297d8-9d26-4fe5-bfee-3f55b02166c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGAM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGAM-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f3d6a62-7ef3-4459-b2a3-947b0ea8d7a9

The open-access MAF lists 32 somatic variants for this specimen: 17 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 12, Intron 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/368 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CREBBP | c.4461C>A p.H1487Q | Missense Mutation (SNP) | VAF 103/419 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99269870; called by muse, mutect2, varscan2
- GPR142 | c.982G>A p.V328M | Missense Mutation (SNP) | VAF 138/520 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs201564934, COSV59518511; called by muse, varscan2
- KCND2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs561063026, COSV58568984; called by muse, mutect2, varscan2
- KLK13 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs143384478, COSV50066926, COSV99335221; called by muse, mutect2, varscan2
- LRRC4B | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 194/632 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs762762398, COSV100975918; called by muse, mutect2, varscan2
- MYO6 | c.2473C>T p.R825* | Nonsense Mutation (SNP) | VAF 19/203 reads (9%) | catalogued as CM148102; called by muse, mutect2
- SLIT2 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1194196591, COSV56569584; called by muse, mutect2, varscan2
- USP43 | c.3004G>A p.V1002M | Missense Mutation (SNP) | VAF 107/379 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs1216468129; called by muse, mutect2, varscan2
- HTR2C | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 117/300 reads (39%) | SIFT tolerated (0.66); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCUR1 | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MGAM2 | c.4048A>C p.K1350Q | Missense Mutation (SNP) | VAF 102/548 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SERINC5 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPTA1 | c.3515C>T p.A1172V | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- STEAP2 | c.357C>A p.N119K | Missense Mutation (SNP) | VAF 72/467 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZAN | c.2180C>A p.P727H | Missense Mutation (SNP) | VAF 102/724 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); called by mutect2, varscan2
- ZNF655 | c.956_957insATAACT p.T319_Q320ins* | Nonsense Mutation (INS) | VAF 68/497 reads (14%) | called by mutect2, pindel, varscan2
- CRH | c.285C>T p.A95= | Silent (SNP) | VAF 276/859 reads (32%) | catalogued as rs759336356; called by muse, mutect2, varscan2
- DLC1 | c.2214G>A p.T738= (on ENST00000276297 / NM_001348081.2; = p.T301= on NM_006094.5) | Silent (SNP) | VAF 111/420 reads (26%) | catalogued as rs770565565; called by muse, varscan2
- EBAG9 | c.564A>G p.Q188= | Silent (SNP) | VAF 77/245 reads (31%) | called by muse, mutect2, varscan2
- EPB41L5 | c.2167C>T p.L723= | Silent (SNP) | VAF 98/349 reads (28%) | called by muse, mutect2, varscan2
- FAM91A1 | c.1317T>C p.F439= | Silent (SNP) | VAF 78/297 reads (26%) | catalogued as rs775102297; called by muse, mutect2
- INAFM2 | c.225G>A p.P75= | Silent (SNP) | VAF 204/685 reads (30%) | called by muse, mutect2, varscan2
- LRRC66 | c.1023C>T p.A341= | Silent (SNP) | VAF 142/558 reads (25%) | catalogued as rs932142959; called by muse, mutect2, varscan2
- MUC2 | c.153C>T p.D51= | Silent (SNP) | VAF 128/512 reads (25%) | catalogued as rs373092469; called by muse, mutect2, varscan2
- PIK3R6 | c.345C>T p.V115= | Silent (SNP) | VAF 143/345 reads (41%) | catalogued as rs766688817; called by muse, mutect2, varscan2
- RIMS1 | c.993G>A p.P331= | Silent (SNP) | VAF 164/681 reads (24%) | catalogued as rs760689367, COSV53438472; called by muse, mutect2, varscan2
- TNC | c.813C>T p.H271= | Silent (SNP) | VAF 138/456 reads (30%) | catalogued as rs1371152512; called by muse, mutect2, varscan2
- TNFRSF1A | c.1206C>T p.S402= | Silent (SNP) | VAF 308/976 reads (32%) | catalogued as rs148334665; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+15252T>C | Intron (SNP) | VAF 56/162 reads (35%) | catalogued as rs1402403572; called by muse, mutect2, varscan2
- NADK | c.264-1858G>A | Intron (SNP) | VAF 172/628 reads (27%) | catalogued as rs562299074; called by muse, mutect2, varscan2
- NEDD4L | c.297+3810C>T | Intron (SNP) | VAF 200/679 reads (29%) | called by muse, mutect2, varscan2
